Somatic mutation profile of tumor specimen TARGET-30-PAVAGS-01A (aliquot TARGET-30-PAVAGS-01A-01D) from TARGET case TARGET-30-PAVAGS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.0 years (1,094 days).
Specimen TARGET-30-PAVAGS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9d64042-0afa-4eaa-9fbf-ca8f833e289c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVAGS-10A (Blood Derived Normal), aliquot TARGET-30-PAVAGS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1daca86b-5467-42a8-9226-cd949a403daf

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs772404861, COSV56009529; called by muse, mutect2, varscan2
